Somatic mutation profile of tumor specimen TCGA-A6-4105-01A (aliquot TCGA-A6-4105-01A-02D-1771-10) from TCGA case TCGA-A6-4105, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.7 years (29,097 days).
Specimen TCGA-A6-4105-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c409551c-6e3c-45d2-89c7-1f27cb29dcc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-4105-10A (Blood Derived Normal), aliquot TCGA-A6-4105-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d1cd2b4-84f9-49df-bff3-431f8527cb69

The open-access MAF lists 178 somatic variants for this specimen: 134 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 41, Nonsense Mutation 6, Frame Shift Ins 3, RNA 2, Splice Site 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 113/184 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6667C>A p.Q2223K | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1057519778, COSV100816071, COSV63878736; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- POLR3B | c.2570+1G>A p.X857_splice | Splice Site (SNP) | VAF 25/45 reads (56%) | catalogued as rs753943393, CS131200, COSV99942888; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 47/79 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7778C>A p.P2593Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71295042; called by muse, mutect2, varscan2
- ACSM3 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.304); catalogued as rs1203320886, COSV99184018; called by muse, mutect2, varscan2
- AMER1 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 128/167 reads (77%) | catalogued as COSV57655167; called by muse, mutect2, varscan2
- ANKS6 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs113520465, COSV62052361; called by muse, mutect2, varscan2
- ANO9 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs986489204, COSV60452048; called by muse, mutect2, varscan2
- APBB1IP | c.224T>G p.I75R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63304962; called by muse, mutect2, varscan2
- APC | c.2706_2707insTCCT p.D903Sfs*2 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | catalogued as COSV99964445; called by mutect2, pindel, varscan2
- ASH2L | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV51700236, COSV51701906; called by muse, mutect2, varscan2
- ATM | c.2122G>T p.E708* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as COSV99586760; called by muse, mutect2, varscan2
- ATP7A | c.4009G>T p.D1337Y | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58454574; called by muse, mutect2, varscan2
- AXDND1 | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV62648944; called by muse, mutect2, varscan2
- BMP7 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 253/353 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs755341380, COSV67780872; called by muse, mutect2, varscan2
- BTC | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs782271380, COSV67547196; called by muse, mutect2, varscan2
- C3orf20 | c.1933A>C p.T645P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99513251; called by muse, mutect2, varscan2
- CDH6 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs764565018, COSV54078937; called by muse, mutect2, varscan2
- CFAP61 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs573435093, COSV55646600; called by muse, mutect2, varscan2
- CHI3L1 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs768428982, COSV55140297; called by muse, mutect2, varscan2
- CHRM5 | c.398C>A p.T133K | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67248725; called by muse, mutect2, varscan2
- CLGN | c.1497dup p.H500Tfs*2 | Frame Shift Ins (INS) | VAF 38/202 reads (19%) | catalogued as rs772112043; called by mutect2, pindel, varscan2
- COL27A1 | c.5314G>A p.V1772M | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs532724249, COSV61931036; called by muse, mutect2, varscan2
- CUBN | c.4421C>A p.P1474H | Missense Mutation (SNP) | VAF 87/166 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64711508; called by muse, mutect2, varscan2
- DENND4C | c.5844G>T p.W1948C (on ENST00000434457 / NM_001330640.2; = p.W1899C on NM_017925.7) | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV59548879; called by muse, mutect2, varscan2
- DOCK4 | c.2867G>C p.R956P | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV70243573; called by muse, mutect2, varscan2
- DOT1L | c.2818G>A p.A940T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1340075396, COSV67113609; called by muse, mutect2, varscan2
- DPY19L1 | c.124T>A p.F42I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60584452; called by muse, mutect2, varscan2
- DYNC1H1 | c.5055G>A p.M1685I | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV64143075; called by muse, mutect2, varscan2
- EGLN3 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs375310922; called by muse, mutect2, varscan2
- ESRRB | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs876657463, COSV55060577; ClinVar: likely benign; called by muse, mutect2, varscan2
- EXOC6 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752268240, COSV53333220; called by muse, mutect2, varscan2
- FAM81B | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.222); catalogued as COSV51987167; called by muse, mutect2, varscan2
- FBN2 | c.7138G>A p.D2380N | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs886059893, COSV52546475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCRL1 | c.95G>T p.S32I | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100839680; called by muse, mutect2, varscan2
- FERMT2 | c.720A>T p.Q240H | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV100448594; called by muse, mutect2
- FLT4 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56123411, COSV99986042; called by muse, mutect2, varscan2
- FRY | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs754777022, COSV66580795; called by muse, mutect2, varscan2
- FZD10 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.269); catalogued as COSV57476048; called by muse, mutect2, varscan2
- GRM2 | c.526T>C p.S176P | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56587657; called by muse, mutect2, varscan2
- GRM8 | c.2516A>T p.Y839F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100279625; called by muse, mutect2, varscan2
- H2AC11 | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.137); catalogued as COSV100345547; called by muse, mutect2, varscan2
- H4C4 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV61591780; called by muse, mutect2, varscan2
- HELZ | c.186C>A p.Y62* | Nonsense Mutation (SNP) | VAF 61/166 reads (37%) | catalogued as COSV62381147; called by muse, mutect2, varscan2
- HTR7 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs768133205, COSV53285537; called by muse, mutect2, varscan2
- ICA1 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768714490, COSV55583837; called by muse, mutect2, varscan2
- IFT80 | c.12G>C p.K4N | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV100425103, COSV58452752; called by muse, mutect2, varscan2
- IL7R | c.1011G>T p.K337N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV100285748; called by muse, varscan2
- KCNC1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as COSV56398750; called by muse, mutect2, varscan2
- KCNT1 | c.1043G>A p.R348H (on ENST00000488444; = p.R367H on NM_020822.3) | Missense Mutation (SNP) | VAF 97/206 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs1400096269, COSV53711523; called by muse, mutect2, varscan2
- KRT23 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as COSV52927357; called by muse, mutect2, varscan2
- LRBA | c.8534T>C p.I2845T | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1294793389, COSV63965618; called by muse, mutect2, varscan2
- LRFN5 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.142); catalogued as rs865936784, COSV53243377, COSV53253488; called by muse, mutect2, varscan2
- LRP1B | c.9200G>A p.G3067D | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101250123; called by muse, mutect2, varscan2
- MAP3K4 | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100814952; called by muse, mutect2, varscan2
- MAST1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.235); catalogued as rs756392687, COSV52242573; called by muse, varscan2
- MEIS1 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as COSV55492601; called by muse, mutect2, varscan2
- MET | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100576917, COSV59272573; called by mutect2, varscan2
- MPDZ | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs777982521, COSV59954675; called by muse, mutect2, varscan2
- MRPS2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs753767783, COSV54093862; called by muse, mutect2, varscan2
- MTCH2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV56768688; called by muse, mutect2, varscan2
- MYH9 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202023656, COSV53393696; called by muse, mutect2, varscan2
- NBAS | c.5869C>T p.H1957Y | Missense Mutation (SNP) | VAF 190/407 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as COSV55738796; called by muse, mutect2, varscan2
- NCAM1 | c.2540A>G p.D847G (on ENST00000316851 / NM_181351.5; = p.D837G on NM_000615.7) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV57525551; called by muse, mutect2, varscan2
- NEB | c.16975C>T p.H5659Y | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs1460424318, COSV51462335; called by muse, mutect2, varscan2
- NEDD4 | c.2392C>G p.P798A (on ENST00000508342 / NM_001284338.1; = p.P379A on NM_006154.4) | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59066849; called by muse, mutect2, varscan2
- NFIC | c.919A>T p.T307S | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.138); catalogued as COSV59417056; called by muse, mutect2, varscan2
- NKD1 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs374394871; called by muse, mutect2, varscan2
- NRBP1 | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51996236; called by muse, mutect2, varscan2
- NT5C | c.395G>T p.R132M | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV55462222; called by muse, mutect2, varscan2
- NTNG1 | c.263G>T p.C88F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53989871; called by muse, mutect2, varscan2
- OGT | c.2647G>C p.E883Q | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65479573, COSV65482772; called by muse, mutect2, varscan2
- OR10K1 | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV56874346; called by muse, mutect2
- OR52D1 | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.052); catalogued as COSV59488392; called by muse, mutect2, varscan2
- PCDH10 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs767880576, COSV52093365; called by muse, mutect2, varscan2
- PCDHAC1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53845440; called by muse, mutect2, varscan2
- PDS5B | c.2576A>G p.H859R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.076); catalogued as rs1229074397, COSV59734982; called by muse, mutect2, varscan2
- PHTF1 | c.1476C>G p.F492L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV63368898; called by muse, mutect2, varscan2
- PIAS1 | c.1366A>G p.K456E | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV99986440; called by mutect2, varscan2
- PIK3C2B | c.3338G>A p.R1113H | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs368018698; called by muse, mutect2, varscan2
- PLEKHA8 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99321246; called by muse, mutect2
- PLXNB2 | c.2143A>G p.M715V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100833786; called by muse, mutect2, varscan2
- PLXND1 | c.3160C>T p.R1054W | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs761956464, COSV100138842; called by muse, mutect2
- POLA2 | c.1228A>T p.I410F | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV99640422; called by muse, mutect2, varscan2
- POLD1 | c.1138-1G>A p.X380_splice | Splice Site (SNP) | VAF 12/91 reads (13%) | catalogued as COSV70957599; called by muse, mutect2, varscan2
- POU6F2 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as rs766931436, COSV101302328; called by muse, mutect2, varscan2
- PPP1R15A | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52340349; called by muse, mutect2, varscan2
- PRDX4 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 123/151 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV65026232; called by muse, mutect2, varscan2
- PREX1 | c.2816A>T p.E939V | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100905996; called by muse, mutect2
- PRMT9 | c.1199T>C p.I400T | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1181471663, COSV59361733; called by muse, mutect2, varscan2
- PRR5 | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs749207913, COSV99134013; called by muse, varscan2
- RHPN1 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs776053563, COSV100000330; called by mutect2, varscan2
- RIC3 | c.917G>C p.C306S (on ENST00000309737 / NM_001206671.4; = p.C305S on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV58305215; called by muse, mutect2, varscan2
- ROBO3 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67303102; called by muse, mutect2
- SDK1 | c.5518G>C p.E1840Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV101269526, COSV67389663; called by muse, mutect2, varscan2
- SFMBT2 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.025); catalogued as rs138425580; called by muse, mutect2, varscan2
- SLC16A12 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.461); catalogued as rs551632763, COSV57955023; called by muse, mutect2, varscan2
- SLC5A8 | c.532A>T p.T178S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.414); catalogued as COSV65987219; called by muse, mutect2, varscan2
- SLC9A8 | c.614C>A p.T205N | Missense Mutation (SNP) | VAF 64/714 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64291633; called by muse, mutect2
- SMYD1 | c.486C>G p.S162R | Missense Mutation (SNP) | VAF 124/296 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as COSV70226109; called by muse, mutect2, varscan2
- SOX3 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV65168100, COSV65168386; called by muse, mutect2, varscan2
- SOX9 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV55428777; called by muse, mutect2, varscan2
- SPAG16 | c.1374A>C p.K458N | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100529210; called by muse, mutect2, varscan2
- SPEG | c.8044G>T p.A2682S | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV56678597; called by muse, mutect2, varscan2
- SPG11 | c.394A>C p.S132R | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as CM1310507, COSV56002535; called by muse, mutect2, varscan2
- SPTB | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs776814615, COSV67635244; called by muse, mutect2, varscan2
- SUN2 | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752150588, COSV53307617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.5503C>T p.R1835C (on ENST00000367255 / NM_182961.4; = p.R1842C on NM_033071.3) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs149448385; called by muse, mutect2, varscan2
- TBXA2R | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated (0.44); PolyPhen benign (0.146); catalogued as COSV64344751; called by muse, mutect2
- TMEM44 | c.1207G>A p.G403R (on ENST00000392432 / NM_001166305.2; = p.G356R on NM_138399.5) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs768376448, COSV56452207; called by muse, mutect2, varscan2
- TRIM36 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 101/162 reads (62%) | catalogued as rs778169722, COSV56693568; called by muse, mutect2, varscan2
- TRPM2 | c.2896C>A p.L966M | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as COSV100308024; called by muse, mutect2, varscan2
- TRPM6 | c.2970C>A p.S990R | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100664972; called by muse, varscan2
- TTN | c.65189G>A p.R21730H (on ENST00000591111; = p.R14306H on NM_003319.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | PolyPhen probably damaging (0.917); catalogued as rs767208489, COSV60367168; called by muse, mutect2, varscan2
- TTN | c.1602A>C p.E534D | Missense Mutation (SNP) | VAF 15/143 reads (10%) | PolyPhen probably damaging (0.969); catalogued as COSV60367194; called by muse, mutect2, varscan2
- TUBB1 | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 255/344 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as COSV53886319, COSV53888460; called by muse, mutect2, varscan2
- TUT7 | c.3616G>A p.V1206I | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV99463710; called by muse, mutect2
- USH1G | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV58883868; called by muse, mutect2, varscan2
- USH2A | c.7259G>C p.S2420T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs1347257686, COSV100227738; called by muse, mutect2, varscan2
- USP53 | c.859A>G p.S287G | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV56797945; called by muse, mutect2, varscan2
- VWA3B | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as COSV68241836; called by muse, mutect2, varscan2
- WDR49 | c.932A>T p.N311I (on ENST00000308378 / NM_001366158.1; = p.N652I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV100391307; called by muse, mutect2, varscan2
- ZC3H13 | c.2674G>C p.E892Q | Missense Mutation (SNP) | VAF 36/537 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.399); catalogued as COSV99667281; called by muse, mutect2
- ZC3H3 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs17857164, COSV52794989; called by muse, mutect2, varscan2
- ZIK1 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as rs761232368, COSV56736809; called by muse, mutect2, varscan2
- ZNF135 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs1423897622, COSV100536377; called by muse, mutect2, varscan2
- ZNF793 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV71325109, COSV71325203; called by muse, mutect2, varscan2
- ZNF91 | c.847A>G p.R283G | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100321905; called by muse, mutect2, varscan2
- MRTFA | c.2957A>G p.D986G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- SYNE1 | c.14914G>T p.E4972* (on ENST00000367255 / NM_182961.4; = p.E4901* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- TP53BP1 | c.309del p.I104Sfs*95 | Frame Shift Del (DEL) | VAF 37/65 reads (57%) | called by mutect2, pindel, varscan2
- WDR59 | c.1199_1200dup p.Q401Cfs*32 | Frame Shift Ins (INS) | VAF 29/159 reads (18%) | called by mutect2, pindel, varscan2
- ADAM20 | c.642C>T p.V214= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1478596547, COSV56456823; called by muse, mutect2, varscan2
- ARAP1 | c.2883G>A p.S961= (on ENST00000393609 / NM_001040118.2; = p.S716= on NM_015242.4) | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs542698728, COSV61991382; called by muse, mutect2, varscan2
- ATP2B3 | c.1182G>A p.T394= | Silent (SNP) | VAF 174/222 reads (78%) | catalogued as rs782157015, COSV54844558, COSV54862482; called by muse, varscan2
- CA13 | c.300C>T p.S100= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs775391404, COSV58797056; called by muse, mutect2, varscan2
- CACNA1A | c.2013C>T p.N671= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as rs779250946, COSV64213264; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNG7 | c.129G>A p.P43= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs376239971; called by muse, mutect2, varscan2
- CSTF2T | c.63G>A p.G21= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV58657614; called by muse, mutect2, varscan2
- DMD | c.498C>T p.G166= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV55903149; called by muse, mutect2, varscan2
- DNAH10 | c.3036G>A p.E1012= (on ENST00000409039; = p.E951= on NM_207437.3) | Silent (SNP) | VAF 66/135 reads (49%) | catalogued as COSV69002681; called by muse, mutect2, varscan2
- DSCAML1 | c.5313G>A p.Q1771= (on ENST00000321322; = p.Q1711= on NM_020693.4) | Silent (SNP) | VAF 96/315 reads (30%) | catalogued as COSV58403419; called by muse, mutect2, varscan2
- DYNC2I1 | c.2916G>T p.V972= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV68107411; called by muse, mutect2, varscan2
- EVA1A | c.246C>T p.S82= | Silent (SNP) | VAF 22/206 reads (11%) | catalogued as COSV52059914; called by muse, mutect2, varscan2
- GRK4 | c.1320G>A p.A440= (on ENST00000398052 / NM_182982.3; = p.A408= on NM_005307.3) | Silent (SNP) | VAF 55/142 reads (39%) | catalogued as rs923470399, COSV61671245; called by muse, mutect2, varscan2
- H6PD | c.219T>A p.G73= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV66232422; called by muse, mutect2, varscan2
- HPDL | c.336G>A p.A112= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as COSV58345033; called by muse, mutect2, varscan2
- HPN | c.891C>A p.G297= | Silent (SNP) | VAF 34/235 reads (14%) | catalogued as COSV99384735; called by muse, mutect2, varscan2
- KRT24 | c.1497T>C p.T499= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV52882123; called by muse, mutect2, varscan2
- LAMB1 | c.4131C>G p.L1377= | Silent (SNP) | VAF 36/215 reads (17%) | catalogued as COSV55970620; called by muse, mutect2, varscan2
- LINS1 | c.1065T>A p.V355= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV59081046; called by muse, mutect2, varscan2
- MAG | c.213G>A p.P71= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs199750254, COSV62699502; called by muse, mutect2, varscan2
- MGAM | c.165G>A p.G55= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs574663869, COSV71885658; called by muse, varscan2
- NALCN | c.5184C>T p.S1728= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs762554597, COSV51965503; called by muse, mutect2, varscan2
- NDUFB4 | c.294C>T p.L98= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV51742985, COSV99481938; called by muse, mutect2, varscan2
- NOC3L | c.147A>T p.L49= | Silent (SNP) | VAF 142/296 reads (48%) | catalogued as COSV64930689; called by muse, mutect2, varscan2
- OR1B1 | c.753C>G p.L251= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV59172464; called by muse, mutect2, varscan2
- OSBP2 | c.816C>T p.A272= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV60250121; called by muse, mutect2, varscan2
- PCDH12 | c.1407G>A p.T469= | Silent (SNP) | VAF 113/203 reads (56%) | catalogued as rs905385036, COSV51519090; called by muse, mutect2, varscan2
- PCDHA10 | c.1497C>T p.G499= | Silent (SNP) | VAF 189/317 reads (60%) | catalogued as rs782516369, COSV56530553, COSV56548468; called by muse, mutect2, varscan2
- PDE4DIP | c.4167G>A p.S1389= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs781923977, COSV57697979, COSV57717926; called by muse, varscan2
- PDZD2 | c.4923G>A p.S1641= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as rs377756230; called by muse, mutect2
- PLXNA4 | c.693G>A p.S231= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs267601294, COSV58162479; called by muse, mutect2, varscan2
- SLC13A2 | c.1281T>C p.G427= | Silent (SNP) | VAF 81/234 reads (35%) | catalogued as COSV58999043; called by muse, mutect2, varscan2
- SLC35D3 | c.564C>T p.T188= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as rs771309847, COSV59378388; called by muse, mutect2, varscan2
- STH | c.81C>T p.C27= | Silent (SNP) | VAF 79/197 reads (40%) | catalogued as rs763740965, COSV52239658; called by muse, mutect2, varscan2
- STK25 | c.1221C>T p.H407= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as rs780044217, COSV50882601; called by muse, mutect2, varscan2
- TBC1D16 | c.1164C>T p.P388= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV60481550; called by muse, mutect2, varscan2
- TEP1 | c.2817C>T p.I939= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1014991881, COSV53000768; called by muse, mutect2, varscan2
- TEPSIN | c.579C>T p.S193= | Silent (SNP) | VAF 71/202 reads (35%) | catalogued as rs200896468, COSV100329461; called by muse, mutect2
- TMEM130 | c.486C>T p.L162= | Silent (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- TREX1 | c.888C>T p.I296= (on ENST00000625293 / NM_033629.6; = p.I286= on NM_007248.5) | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV99603801; called by muse, mutect2, varscan2
- TRPM1 | c.1203G>T p.L401= | Silent (SNP) | VAF 16/346 reads (5%) | called by muse, mutect2
- LINC02145 | n.412C>T | RNA (SNP) | VAF 41/127 reads (32%) | catalogued as rs756270974; called by muse, mutect2, varscan2
- MIR323A | n.36G>A | RNA (SNP) | VAF 74/262 reads (28%) | catalogued as rs1040944663; called by muse, varscan2
- RFX4 | c.44-7485C>T | Intron (SNP) | VAF 32/178 reads (18%) | catalogued as rs145238438; called by muse, mutect2, varscan2
